Somatic mutation profile of tumor specimen TCGA-36-2543-01A (aliquot TCGA-36-2543-01A-01D-1526-09) from TCGA case TCGA-36-2543, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 85.5 years (31,211 days).
Specimen TCGA-36-2543-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b541fac-7c10-4e77-8c96-216963ba37cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2543-10A (Blood Derived Normal), aliquot TCGA-36-2543-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60f624e5-891c-4bcd-af97-67f34ae94212

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Splice Site 3, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 56/228 reads (25%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NF1 | c.6772C>T p.R2258* (on ENST00000358273 / NM_001042492.3; = p.R2237* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 91/141 reads (65%) | catalogued as rs876658541, CM000815, COSV62192184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 65/104 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691025, COSV52677105, COSV52952688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.3539G>A p.R1180Q | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as rs1389319442, COSV50754991; called by muse, mutect2, varscan2
- ADGRG4 | c.2766T>G p.S922R | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV54969474; called by muse, mutect2, varscan2
- ADRM1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374711; called by muse, mutect2, varscan2
- AMPD2 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 246/383 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV56651424; called by muse, mutect2, varscan2
- ATF6 | c.954A>T p.E318D | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63410589; called by muse, mutect2, varscan2
- BRINP3 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs772136142, COSV66539636; called by muse, mutect2, varscan2
- CATSPERE | c.2183T>C p.I728T | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63682991; called by muse, mutect2, varscan2
- CNTNAP3 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs201209922; called by muse, mutect2, varscan2
- CORIN | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 99/165 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs571162211, COSV56687593; called by muse, mutect2, varscan2
- COX14 | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 205/569 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58725059; called by muse, mutect2, varscan2
- EEFSEC | c.1690_1692del p.E564del | In Frame Del (DEL) | VAF 67/177 reads (38%) | catalogued as rs1559963629; called by pindel, varscan2
- FKBP14 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 166/451 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs780572118, COSV56108079; called by muse, mutect2, varscan2
- FOXD4 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 80/473 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58698344, COSV58703688; called by muse, mutect2, varscan2
- GCNT4 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV59281886; called by muse, mutect2, varscan2
- GRIK3 | c.1754+1G>T p.X585_splice | Splice Site (SNP) | VAF 81/192 reads (42%) | catalogued as COSV66148353; called by muse, mutect2, varscan2
- HEATR1 | c.1564G>C p.V522L | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV63983537; called by muse, mutect2, varscan2
- HMGCL | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV99353669; called by muse, mutect2, varscan2
- HNRNPU | c.961G>A p.E321K (on ENST00000283179; = p.E383K on NM_004501.3) | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99309805; called by muse, mutect2
- IL1RL1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.217); catalogued as rs747989282, COSV52121539; called by muse, mutect2, varscan2
- IQCF2 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs537390720, COSV60762059; called by muse, mutect2, varscan2
- ITGB5 | c.2186G>C p.G729A | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.916); catalogued as COSV99950330; called by muse, mutect2
- KMT2A | c.11356C>T p.R3786C | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63284485; called by muse, mutect2
- LYN | c.790+2T>G p.X264_splice | Splice Site (SNP) | VAF 222/593 reads (37%) | catalogued as COSV70206573; called by muse, varscan2
- MAPK14 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 159/472 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV57698149; called by muse, mutect2, varscan2
- MID2 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs1026584998, COSV53308203; called by muse, mutect2, varscan2
- MTA2 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53871102, COSV99603967; called by muse, mutect2, varscan2
- NUDT22 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs143695088, COSV54176174, COSV99656017; called by muse, mutect2, varscan2
- NUP214 | c.2645T>C p.L882P | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845118; called by muse, mutect2
- OR51F1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100598624; called by muse, mutect2
- OR5J2 | c.746C>G p.T249S | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as COSV56623740; called by muse, mutect2, varscan2
- OTOF | c.2471A>T p.K824M (on ENST00000272371 / NM_194248.3; = p.K77M on NM_004802.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.319); catalogued as COSV55522261, COSV55524042; called by muse, mutect2, varscan2
- PAK6 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53048526; called by muse, mutect2, varscan2
- PAPOLB | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV68204177; called by muse, mutect2, varscan2
- PCGF6 | c.344C>A p.S115* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs139160000, COSV100461649; called by muse, mutect2
- QSOX1 | c.1289-1G>C p.X430_splice | Splice Site (SNP) | VAF 35/73 reads (48%) | catalogued as COSV62581864; called by muse, mutect2, varscan2
- RET | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV60711107; called by muse, mutect2, varscan2
- RWDD4 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100419049; called by muse, mutect2
- SAMD9L | c.1790G>C p.R597T | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV59080532, COSV59086152; called by muse, mutect2, varscan2
- SBF2 | c.5367T>G p.I1789M | Missense Mutation (SNP) | VAF 127/483 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56314124; called by muse, mutect2, varscan2
- SDR16C5 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58128853; called by muse, mutect2, varscan2
- SETD1A | c.674C>G p.A225G | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV52693545; called by muse, mutect2, varscan2
- SLC9C1 | c.1916T>A p.I639N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV59894721; called by muse, mutect2, varscan2
- SMCR8 | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58181618; called by muse, mutect2, varscan2
- TBCEL | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52463224; called by muse, mutect2, varscan2
- TESK1 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV52412668; called by muse, mutect2, varscan2
- TMEM71 | c.691C>G p.Q231E (on ENST00000523829 / NM_001382398.1; = p.Q212E on NM_144649.3) | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV63459823; called by muse, mutect2, varscan2
- TRPM6 | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 162/269 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62504431; called by muse, mutect2, varscan2
- UBR5 | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 148/270 reads (55%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.678); catalogued as COSV55302613; called by muse, mutect2, varscan2
- YIF1B | c.87G>C p.Q29H (on ENST00000339413 / NM_001039673.3; = p.Q14H on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56651892; called by muse, mutect2, varscan2
- ZNF438 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59201960; called by muse, mutect2, varscan2
- ZNF875 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV60992431, COSV60994517; called by muse, mutect2, varscan2
- FCGBP | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AFF2 | c.1308T>C p.L436= | Silent (SNP) | VAF 94/462 reads (20%) | catalogued as COSV54011112; called by mutect2, varscan2
- ARID4B | c.597T>G p.P199= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV51612798; called by muse, mutect2, varscan2
- CCDC112 | c.912T>C p.H304= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV65474182; called by muse, mutect2, varscan2
- CHRDL2 | c.1014C>G p.V338= | Silent (SNP) | VAF 13/442 reads (3%) | catalogued as COSV99733512; called by muse, mutect2
- CNTN1 | c.393C>T p.S131= | Silent (SNP) | VAF 131/319 reads (41%) | catalogued as COSV61646690; called by muse, mutect2, varscan2
- DYSF | c.3192G>A p.A1064= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs764414374, COSV50639237; called by muse, mutect2, varscan2
- EHD1 | c.741C>T p.P247= | Silent (SNP) | VAF 94/445 reads (21%) | catalogued as rs374259413, COSV57737231; called by muse, mutect2, varscan2
- FARSA | c.1281G>A p.K427= | Silent (SNP) | VAF 36/178 reads (20%) | catalogued as COSV53368949; called by muse, mutect2, varscan2
- GPR6 | c.285G>A p.A95= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51574292; called by muse, mutect2, varscan2
- GYPA | c.282C>G p.L94= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV51636694; called by muse, mutect2, varscan2
- ITPR3 | c.5182C>T p.L1728= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV65412534; called by muse, mutect2
- KDM4B | c.192C>T p.D64= | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as rs753456068, COSV50272981; called by muse, mutect2, varscan2
- KRT79 | c.750G>C p.V250= | Silent (SNP) | VAF 264/787 reads (34%) | catalogued as COSV57942807; called by muse, mutect2, varscan2
- LTA | c.300G>C p.L100= | Silent (SNP) | VAF 161/651 reads (25%) | catalogued as COSV69305482; called by muse, mutect2, varscan2
- NPAS1 | c.786C>G p.V262= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV71384453; called by muse, mutect2, varscan2
- PRKCA | c.1620T>G p.G540= | Silent (SNP) | VAF 72/447 reads (16%) | catalogued as COSV66101678; called by muse, mutect2, varscan2
- DISC1 | c.1117+20571C>G | Intron (SNP) | VAF 17/316 reads (5%) | catalogued as COSV99697044; called by muse, mutect2
- GCNT2 | c.926-35128G>A | Intron (SNP) | VAF 147/294 reads (50%) | catalogued as COSV53944988; called by muse, mutect2, varscan2
